Gene-level copy-number profile of tumor specimen TCGA-56-8628-01A from TCGA case TCGA-56-8628, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 78.9 years (28,805 days).
Specimen TCGA-56-8628-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.572f8290-42e8-43e2-b2de-46bd04ecd818.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-8628-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5c0a6438-0db5-4e8b-9fac-569caab6e37d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 232; copy number 1: 18,586; copy number 2: 32,296; copy number 3: 5,499; copy number 4: 2,179; copy number 5: 120; copy number 6: 469; copy number 7: 231; copy number 8: 11; copy number 9: 20; copy number 10: 51; copy number 14: 37; copy number 16: 87.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-8628-01A-11D-2391-01): tumor purity 0.41, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 231 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:27,357,825–27,713,352, 16 genes: ZNF204P, ZNF391, AL031118.1, MCFD2P1, ZNF184, AL021918.4, AL021918.5, AL021918.3, AL021918.2, AL021918.1, HNRNPA1P1, CD83P1, RNU6-471P, RPL8P1, AL009179.2, LINC01012.
- chr8:150,584–2,728,577, 54 genes (within-gene range 0–1): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2.
- chr8:6,036,433–7,056,739, 32 genes: AC079054.1, AC009435.1, AC016065.1, MCPH1, AC016065.2, ANGPT2, AC018398.2, AF287957.1, MCPH1-AS1, MIR8055, AGPAT5, MIR4659A, MIR4659B, AF233439.2, XKR5, GS1-24F4.2, DEFB1, RPL23AP96, DEFA6, AF233439.1, DEFA4, DEFA8P, DEFA9P, DEFA10P, DEFA1, DEFT1P, DEFA1B, DEFT1P2, DEFA3, DEFA11P, DEFA7P, DEFA5.
- chr9:16,917,511–17,503,923, 7 genes: AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1.
- chr9:17,589,161–17,591,318, 1 gene: PABPC1P11.
- chr10:106,970,021–106,970,150, 1 gene: RNA5SP325.
- chr13:18,467,172–22,706,206, 119 genes (broad region; genes not listed).
- chr21:18,269,116–18,485,879, 1 gene (within-gene range 0–2): TMPRSS15.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,026 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:99,215,224–99,529,985, 4 genes, copy number 5: ACTG1P13, AC107297.1, AC078828.1, AC107029.1.
- chr3:180,161,886–182,985,953, 56 genes, copy number 9–14: RNA5SP149, AC134503.1, GAPDHP36, RALBP1P1, LINC02053, U8, AC125618.1, RNU6-486P, AC068298.1, TTC14, CCDC39, CCDC39, CCDC39-AS1, AC108734.4, RN7SL229P, AC108734.3, AC108734.2, FLYWCH1P1, FXR1, AC108734.1, DNAJC19, SOX2-OT, AC083904.1, RNU6-4P, FAUP2, AC068308.1, RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.2, AC012081.1, AC109131.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1.
- chr3:183,016,255–183,017,808, 1 gene, copy number 14: MCCC1-AS1.
- chr3:183,635,610–186,772,986, 87 genes, copy number 16 (within-gene range 3–16) (broad region; genes not listed).
- chr4:77,157,207–77,433,388, 4 genes, copy number 6 (within-gene range 2–6): CCNG2, AC008638.3, AC008638.2, AC008638.1.
- chr5:58,198–31,595,669, 465 genes, copy number 5–6 (broad region; genes not listed).
- chr5:31,657,218–31,840,971, 11 genes, copy number 6: AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2.
- chr5:32,124,716–50,443,248, 229 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr8:32,911,493–33,600,023, 19 genes, copy number 6: RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9, AC104027.1, RNU6-528P, AC067838.1, FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26.
- chr8:33,641,581–33,641,939, 1 gene, copy number 6: BUD31P1.
- chr8:34,784,028–35,796,550, 7 genes, copy number 7 (within-gene range 2–7): LINC01288, AC087343.1, AC099685.1, UNC5D, AC090740.1, LSM12P1, AC105230.1.
- chr8:37,784,191–41,309,473, 78 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr8:41,840,059–42,332,460, 11 genes, copy number 8 (within-gene range 3–8): RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB.
- chr8:78,148,101–78,956,082, 12 genes, copy number 5 (within-gene range 4–5): AC084706.1, PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, AC068700.2, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605.
- chr8:127,578,473–128,564,679, 18 genes, copy number 5–7: AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr8:139,096,305–139,508,971, 5 genes, copy number 5: AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1.
- chr19:39,553,034–39,786,291, 18 genes, copy number 5 (within-gene range 2–5): AC011500.2, AC011500.1, RPS29P24, RPS29P25, RPS29P26, LGALS13, AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC, LEUTX.

Autosomal genes at a single copy (total copy number 1): 16,200. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
